FM case AD3546 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Nasopharynx.
https://portal.gdc.cancer.gov/cases/da97eab3-82ed-4b82-8041-6ef46e004c7b

Female, 43.5 years: Carcinoma, undifferentiated, NOS (ICD-O-3 8020/3) of the overlapping lesion of nasopharynx; metastasis biopsied or resected from the nasal cavity. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
